FM case AD14065 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/e4ca8b8f-40ca-479b-9c4f-a7bb0139201a

Female, 75.4 years: Small cell carcinoma, NOS (ICD-O-3 8041/34) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
